Somatic mutation profile of tumor specimen MMRF_1355_1_BM_CD138pos (aliquot MMRF_1355_1_BM_CD138pos_T1_KAS5U_L01927) from MMRF case MMRF_1355, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.0 years (27,387 days).
Specimen MMRF_1355_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 859d0181-5070-4071-acba-ac107651695a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1355_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1355_2_PB_Whole_C1_KAS5U_L01938; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43abf0ea-0b6b-4f35-884e-2c8369ee9128

The open-access MAF lists 102 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 24, Silent 13, Intron 10, 5'Flank 4, 5'UTR 3, 3'Flank 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTR | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs121918084, CM930709; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATG9B | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs756553369, COSV99871276; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs143441354; called by muse, mutect2
- CPNE8 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs926258147, COSV58838522; called by muse, mutect2, varscan2
- DDX17 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247223; called by muse, mutect2, varscan2
- FAM110B | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.479); catalogued as rs766614164, COSV64063152; called by muse, mutect2
- FAM90A1 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs146601021; called by muse, varscan2
- FGFR1 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1162148796, COSV58343531; called by muse, mutect2, varscan2
- FRAS1 | c.4064C>T p.A1355V | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV53621512; called by muse, mutect2, varscan2
- HLA-DRB1 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs1237430078; called by muse, mutect2, varscan2
- IGHJ5 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | PolyPhen benign (0.003); catalogued as rs782494105; called by muse, varscan2
- IGHV2-70 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs568191048; called by muse, varscan2
- LAMA1 | c.2453G>C p.W818S | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs140314525; called by muse, mutect2, varscan2
- LAMA4 | c.5381G>A p.R1794H (on ENST00000230538 / NM_001105206.3; = p.R1787H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782780328, COSV57900553, COSV57902994; called by muse, mutect2, varscan2
- LTB | c.163-8C>G | Splice Region (SNP) | VAF 140/346 reads (40%) | catalogued as rs767488608, COSV53001079; called by muse, mutect2, varscan2
- MAEA | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1300147250; called by muse, mutect2, varscan2
- NLRP12 | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376902606, COSV100145023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGA8 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.305); catalogued as COSV53916147; called by muse, mutect2, varscan2
- PIEZO2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs749474073, COSV57434363; called by muse, mutect2, varscan2
- RIPK4 | c.1978G>A p.A660T (on ENST00000352483; = p.A612T on NM_020639.3) | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371705604, COSV60186127; called by muse, mutect2, varscan2
- STOX2 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 118/297 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1250261800, COSV57855444; called by muse, mutect2, varscan2
- USP2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs752201967, COSV52727846; called by muse, mutect2, varscan2
- WNT3A | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52733025; called by muse, mutect2
- ZNF211 | c.205dup p.T69Nfs*13 (on ENST00000347302 / NM_198855.4; = p.T82Nfs*13 on NM_006385.5) | Frame Shift Ins (INS) | VAF 51/397 reads (13%) | catalogued as rs756785599; called by mutect2, pindel, varscan2
- ADGRG4 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AJM1 | c.2734T>C p.F912L | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ASAP2 | c.1941C>G p.I647M | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, varscan2
- BATF | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 111/171 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- BCL6 | c.1966A>T p.K656* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- CCDC38 | c.921C>A p.N307K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL9A1 | c.1745A>T p.K582M | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF1D | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.703); called by muse, mutect2
- GLIPR1L2 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOSR2 | c.729T>G p.F243L | Missense Mutation (SNP) | VAF 74/193 reads (38%) | PolyPhen benign (0.302); called by muse, mutect2, varscan2
- HUS1B | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- IGHV4-34 | c.237T>G p.H79Q | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1-33 | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, varscan2
- KLHL26 | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLHL26 | c.1680G>C p.K560N | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- METTL2B | c.110+2T>G p.X37_splice | Splice Site (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RABGAP1 | c.913G>C p.G305R | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RAE1 | c.334dup p.M112Nfs*7 | Frame Shift Ins (INS) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- SETX | c.367T>G p.L123V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FCGBP | c.10125C>T p.G3375= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs1223786610; called by muse, mutect2, varscan2
- IGHJ3 | c.49G>C p.*17= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as rs368175492; called by muse, varscan2
- IGHV2-70D | c.237C>T p.F79= | Silent (SNP) | VAF 42/52 reads (81%) | called by muse, mutect2, varscan2
- IGKV1-27 | c.135C>T p.C45= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs1292131674; called by muse, mutect2, varscan2
- INPP4B | c.411G>A p.P137= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as rs763236869; called by muse, mutect2, varscan2
- KNDC1 | c.1215A>T p.P405= | Silent (SNP) | VAF 78/182 reads (43%) | called by muse, mutect2, varscan2
- MEF2D | c.1386C>T p.A462= | Silent (SNP) | VAF 47/143 reads (33%) | catalogued as COSV100560169; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1863C>T p.I621= | Silent (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- NAV1 | c.87C>T p.G29= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- NFAT5 | c.1164G>A p.L388= | Silent (SNP) | VAF 101/208 reads (49%) | called by muse, mutect2, varscan2
- NRXN2 | c.1608G>A p.R536= | Silent (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- PRDM15 | c.3609G>A p.Q1203= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, varscan2
- SMC5 | c.684A>G p.S228= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2
- ABCF3 | c.-128C>G | 5'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021134 G>A | 5'Flank (SNP) | VAF 71/141 reads (50%) | catalogued as rs895189444; called by muse, mutect2, varscan2
- BCL7A | chr12:122021135 G>A | 5'Flank (SNP) | VAF 71/141 reads (50%) | catalogued as rs185015243; called by muse, mutect2, varscan2
- BCL7A | chr12:122021550 T>G | 5'Flank (SNP) | VAF 47/90 reads (52%) | called by muse, varscan2
- BCL7A | chr12:122021607 C>G | 5'Flank (SNP) | VAF 26/50 reads (52%) | called by muse, varscan2
- BEND4 | c.*2588G>A | 3'UTR (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- BRAF | c.1298-39T>C | Intron (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- CBLB | c.*1038A>G | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- CISD2 | c.*802G>A | 3'UTR (SNP) | VAF 29/116 reads (25%) | catalogued as rs1433426308; called by muse, mutect2, varscan2
- DHX34 | c.-140C>T | 5'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- EPHA5 | c.*1725T>A | 3'UTR (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- FAM167A | c.*34G>T | 3'UTR (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- FAM180B | c.*580C>G | 3'UTR (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- GABRD | c.1059+64G>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- GFRA2 | c.*54G>A | 3'UTR (SNP) | VAF 45/97 reads (46%) | catalogued as rs1293939443; called by muse, mutect2, varscan2
- IGKV1-33 | c.-13A>T | 5'UTR (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- L1CAM | c.3458-69C>T | Intron (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2
- LARGE1 | c.492-38C>T | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- LIN28A | c.*2614G>A | 3'UTR (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- LRPAP1 | c.*1283G>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- MAN2C1 | c.1219-31C>T | Intron (SNP) | VAF 27/39 reads (69%) | catalogued as rs763222258; called by muse, mutect2, varscan2
- MTHFD2 | c.*32C>T | 3'UTR (SNP) | VAF 23/285 reads (8%) | called by muse, mutect2
- OPRM1 | c.1164+93G>A | Intron (SNP) | VAF 85/200 reads (43%) | called by muse, mutect2, varscan2
- PAWR | c.*6556T>A | 3'UTR (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- PDZD2 | c.*956G>C | 3'UTR (SNP) | VAF 71/152 reads (47%) | called by muse, mutect2, varscan2
- PFKFB4 | c.*1361G>A | 3'UTR (SNP) | VAF 48/116 reads (41%) | called by muse, mutect2, varscan2
- PSD4 | c.1250-87C>T | Intron (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- PTN | c.*465T>C | 3'UTR (SNP) | VAF 40/172 reads (23%) | called by muse, mutect2, varscan2
- RGS7BP | c.*1255A>C | 3'UTR (SNP) | VAF 33/114 reads (29%) | called by muse, mutect2, varscan2
- RPS4Y1 | c.*14C>T | 3'UTR (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2
- RUFY1 | c.311-123_311-118del | Intron (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- SLIT1 | c.*2594C>A | 3'UTR (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- SLITRK2 | chrX:145828732 G>T | 3'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- SNORD116-26 | chr15:25099633 T>A | 3'Flank (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- STK17B | c.*3590C>A | 3'UTR (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- SUSD6 | c.*4031T>A | 3'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs919142609, COSV61366210; called by muse, mutect2, varscan2
- SYT7 | c.*2568C>T | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- TMC2 | c.1872+102C>A | Intron (SNP) | VAF 38/233 reads (16%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.*1134C>T | 3'UTR (SNP) | VAF 131/416 reads (31%) | called by muse, mutect2, varscan2
- TNS3 | c.*1492C>T | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.34523-383G>A | Intron (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- USP25 | chr21:15879179 A>G | 3'Flank (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- ZNF516 | c.*444C>A | 3'UTR (SNP) | VAF 53/251 reads (21%) | called by muse, mutect2, varscan2
- ZNF772 | c.*2454G>A | 3'UTR (SNP) | VAF 30/193 reads (16%) | called by muse, mutect2, varscan2
